Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4371, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4371-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Body. Tumor configuration: Exophytic (polypoid). Tumor size: 3.0 x 4.0 x 1.0 cm. Histologic type: Adenocarcinoma. Histologic grade: Well differentiated. Extent of invasion: Muscularis propria. Lymph nodes: Not specified. Margins — Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 19fc44ea-d8b2-48b1-a2a2-9cc7881058b4 (TCGA-BR-4371.1FEDB1D4-8CC9-4264-B9E2-E7B37467D68B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).